Gene-level copy-number profile of tumor specimen HTMCP-03-06-02068-01B from CGCI case HTMCP-03-06-02068, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.1 years (21,573 days).
Specimen HTMCP-03-06-02068-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 86cc1266-a087-4804-8c9a-62cd646c472f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02068-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/a4384f24-5a25-4e1f-9050-3df1bb209de1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 3,141; copy number 2: 21,576; copy number 3: 20,673; copy number 4: 6,274; copy number 5: 4,972; copy number 6: 869; copy number 7: 219; copy number 8: 610; copy number 10: 31; copy number 12: 1; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,643,286–132,671,579, 2 genes (within-gene range 0–1): LYPD1, AC010974.1.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr7:45,789,585–45,789,688, 1 gene: RNU6-241P.
- chr9:62,838,824–62,934,964, 8 genes: PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1.
- chr11:4,287,499–4,339,244, 3 genes: SSU72P4, SSU72P3, SSU72P7.
- chr12:2,603,350–2,607,440, 1 gene (within-gene range 0–1): CACNA1C-AS3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,704 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,095,974–148,288,951, 105 genes, copy number 5 (broad region; genes not listed).
- chr1:149,754,301–149,754,710, 1 gene, copy number 5: AC243772.1.
- chr1:149,923,317–200,966,668, 1,225 genes, copy number 5–6 (broad region; genes not listed).
- chr1:205,142,505–224,437,033, 352 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:224,896,262–230,007,195, 160 genes, copy number 5 (broad region; genes not listed).
- chr2:8,721,081–9,770,341, 23 genes, copy number 5: KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3.
- chr2:12,780,593–28,850,611, 273 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:31,522,480–58,296,817, 388 genes, copy number 5 (broad region; genes not listed).
- chr2:60,719,640–84,350,774, 432 genes, copy number 5–6 (broad region; genes not listed).
- chr2:87,125,198–87,348,728, 7 genes, copy number 6–7: AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268.
- chr2:87,439,523–87,767,359, 8 genes, copy number 6 (within-gene range 4–6): LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4.
- chr3:130,048,143–197,627,906, 1,133 genes, copy number 5–12 (broad region; genes not listed).
- chr3:197,660,565–198,123,232, 21 genes, copy number 7: AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:45,890,216–45,895,970, 1 gene, copy number 6: AC122694.1.
- chr7:142,656,701–142,802,748, 32 genes, copy number 5: TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr9:4,984,390–6,727,438, 54 genes, copy number 5 (within-gene range 4–5): JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:64,369,394–64,413,142, 2 genes, copy number 14: ANKRD20A4P, RNU6-1193P.
- chr11:33,376,108–33,674,102, 1 gene, copy number 5 (within-gene range 2–5): KIAA1549L.
- chr11:33,450,646–34,102,610, 16 genes, copy number 5: AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1, AC090469.1, CAPRIN1.
- chr11:34,404,663–36,697,867, 44 genes, copy number 5: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr11:64,359,148–64,372,215, 2 genes, copy number 5: RPS6KA4, MIR1237.
- chr12:30,628,988–32,396,147, 62 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–22,982,258, 357 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr14:30,734,926–51,599,952, 315 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:51,522,864–51,522,967, 1 gene, copy number 5 (within-gene range 4–5): RNU6-1291P.
- chr14:52,552,836–52,774,989, 5 genes, copy number 6: GPR137C, ERO1A, AL133453.1, PSMC6, STYX.
- chr14:54,938,949–64,387,986, 180 genes, copy number 5 (broad region; genes not listed).
- chr14:72,969,451–74,084,492, 51 genes, copy number 5: ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2, PSEN1, AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2, NUMB, AC005280.3, AC005280.2, AC005280.1, HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6, NDUFB8P1, DNAL1, RNU6-240P, AC006146.1, PNMA1, MIDEAS, MIR4505, AC005520.2, LINC02274, AC005520.4, PTGR2, AC005520.1, Y_RNA, AC005520.5, ZNF410, AC005480.1, AC005520.3, Y_RNA, FAM161B, COQ6, ENTPD5, AC005480.2, BBOF1, ALDH6A1.
- chr14:76,886,377–77,769,742, 41 genes, copy number 5: RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178.
- chr14:90,847,861–92,172,145, 26 genes, copy number 5: RPS6KA5, DGLUCY, RNU7-30P, SNORA11B, GPR68, AL135818.1, AL135818.2, CCDC88C, AL133153.2, AL133153.1, PPP4R3A, AL133373.2, AL133373.3, CATSPERB, POLR3GP1, NANOGP7, AL121839.1, U3, AL121839.2, TC2N, FBLN5, TRIP11, AL049872.1, ATXN3, NDUFB1, CPSF2.
- chr14:101,761,798–101,927,989, 1 gene, copy number 5 (within-gene range 4–5): PPP2R5C.
- chr14:101,833,435–104,117,514, 80 genes, copy number 5 (broad region; genes not listed).
- chr17:40,219,304–40,284,136, 1 gene, copy number 5: WIPF2.
- chr17:50,055,968–63,864,379, 351 genes, copy number 5 (broad region; genes not listed).
- chr17:67,070,444–77,281,897, 290 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:80,966,239–83,240,804, 145 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:22,088,060–22,130,729, 2 genes, copy number 5: AC091043.1, RNU6ATAC20P.
- chr19:43,401,496–49,961,172, 394 genes, copy number 5 (broad region; genes not listed).
- chr19:57,317,208–58,605,223, 118 genes, copy number 5 (broad region; genes not listed).
- chr20:64,073,181–64,079,988, 2 genes, copy number 5: RGS19, MIR6813.

Autosomal genes at a single copy (total copy number 1): 3,141. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
